TCGA case TCGA-DV-5567 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: NCI Urologic Oncology Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aba26e6b-f11c-4ae6-a0d6-85bdd2060e8f

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (4)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 40.1 years (14,642 days); Year of diagnosis: 2008; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Synchronous primary of the kidney (histology not recorded by GDC). Laterality: Left.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Prior primary; AJCC staging edition: 5th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 45.6 years (16,646 days); Days to diagnosis: 2,004 days (5.5 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (6 entries)
- Days to follow up: 364 days; Disease response: With Tumor.
- Days to follow up: 910 days (2.5 years); Disease response: With Tumor.
- Days to follow up: 1,470 days (4.0 years); Disease response: With Tumor.
- Day 2,004 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Other.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.

Molecular and laboratory tests
- Platelets: Normal.
- Lactate Dehydrogenase: Normal.
- Leukocytes: Elevated.
- Calcium: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DV-5567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.1.
  Slide TCGA-DV-5567-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-DV-5567-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-DV-5567-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DV-5567-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event surgery met: No.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -2897.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy L KIRC. No systemic chemotherapy or radiation. Patient with synchronous L kidney cancer.
- Synchronous malignancy: Prior malignancy L KIRC. No systemic chemotherapy or radiation. Patient with synchronous L kidney cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,004 days; disease-specific survival: no event (censored), 2,004 days; disease-free interval: event (new tumor event after initially disease-free), 2,004 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,004 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DV-5567-01A-01D-1530-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0.
